Somatic mutation profile of tumor specimen TCGA-4Z-AA7Y-01A (aliquot TCGA-4Z-AA7Y-01A-11D-A391-08) from TCGA case TCGA-4Z-AA7Y, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 60.4 years (22,056 days).
Specimen TCGA-4Z-AA7Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92dff9b2-d7e9-492e-8e0f-f2f551ad695d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA7Y-10A (Blood Derived Normal), aliquot TCGA-4Z-AA7Y-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50befdbf-28f9-4e64-8fec-b3d219175e3d

The open-access MAF lists 325 somatic variants for this specimen: 235 protein-altering or splice-affecting, 83 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 83, Nonsense Mutation 25, Frame Shift Del 6, Frame Shift Ins 2, Intron 2, 5'UTR 2, RNA 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 75/77 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 30/53 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 30/52 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRA2 | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59442513; called by mutect2, varscan2
- ADGRF2 | c.343G>T p.D115Y (on ENST00000296862 / NM_001368115.2; = p.D47Y on NM_153839.7) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs1468639313, COSV57287695; called by muse, mutect2
- AFTPH | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53217132; called by muse, mutect2, varscan2
- AGAP6 | c.298G>C p.E100Q (on ENST00000374056 / NM_001365867.1; = p.E123Q on NM_001077665.2) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV65017550; called by muse, mutect2, varscan2
- AGL | c.1391G>C p.G464A | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV54051178, COSV99649720; called by muse, mutect2, varscan2
- AGTRAP | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs1195143482, COSV100065184; called by muse, mutect2, varscan2
- AKT3 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV55630311; called by muse, mutect2, varscan2
- AMER1 | c.1371G>C p.Q457H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV57658639, COSV57668511; called by muse, mutect2, varscan2
- ANKH | c.837G>C p.L279F | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52477126, COSV52479341; called by muse, varscan2
- ANKRD17 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs1442031872, COSV58218425; called by muse, mutect2, varscan2
- APC2 | c.3746G>A p.R1249H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs894952910, COSV52017448; ClinVar: uncertain significance; called by muse, varscan2
- APOA5 | c.301del p.E101Rfs*3 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | catalogued as COSV57065314; called by mutect2, pindel, varscan2
- ARAP2 | c.269C>A p.S90* | Nonsense Mutation (SNP) | VAF 38/107 reads (36%) | catalogued as COSV100394170; called by muse, mutect2, varscan2
- ARNT | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV62230319; called by muse, mutect2, varscan2
- ARRB2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV52617001; called by muse, mutect2, varscan2
- ASPSCR1 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100144727; called by muse, mutect2, varscan2
- ATP2B2 | c.1467G>C p.K489N (on ENST00000352432; = p.K455N on NM_001683.5) | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59493938; called by muse, mutect2, varscan2
- BCO2 | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 69/176 reads (39%) | catalogued as rs903302413, COSV100730241; called by muse, mutect2, varscan2
- BIRC6 | c.13198C>T p.R4400W | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775855234, COSV70197809; called by muse, mutect2, varscan2
- BRD7 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 19/25 reads (76%) | catalogued as rs1361136798, COSV101164709; called by muse, mutect2, varscan2
- BRINP2 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.188); catalogued as COSV64176855; called by muse, mutect2, varscan2
- BRIP1 | c.1958C>G p.S653* | Nonsense Mutation (SNP) | VAF 43/101 reads (43%) | catalogued as COSV99369382; called by muse, mutect2, varscan2
- BRPF1 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as COSV57404223; called by muse, mutect2, varscan2
- CADM2 | c.520G>C p.E174Q (on ENST00000407528 / NM_001167674.2; = p.E176Q on NM_153184.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV67367415, COSV67371063, COSV99081108; called by muse, mutect2, varscan2
- CALHM5 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV62067592; called by muse, mutect2, varscan2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs754747174; called by mutect2, pindel, varscan2
- CARMIL3 | c.2745G>T p.K915N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as COSV57725802; called by muse, mutect2, varscan2
- CARMIL3 | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.746); catalogued as COSV57725810; called by muse, mutect2, varscan2
- CARS1 | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV53452920; called by muse, mutect2, varscan2
- CASQ2 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54769681; called by muse, mutect2, varscan2
- CD96 | c.994G>A p.E332K (on ENST00000283285 / NM_198196.3; = p.E316K on NM_005816.5) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV51915008; called by muse, mutect2, varscan2
- CD96 | c.1119G>C p.K373N (on ENST00000283285 / NM_198196.3; = p.K357N on NM_005816.5) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV51915020; called by muse, mutect2, varscan2
- CDC25A | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.78); PolyPhen benign (0.183); catalogued as COSV56770312; called by muse, mutect2, varscan2
- CDH2 | c.1399C>G p.Q467E | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52277109; called by muse, mutect2, varscan2
- CEBPZ | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.258); catalogued as COSV52205781; called by muse, mutect2, varscan2
- CHD1 | c.4606C>T p.H1536Y | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.14); catalogued as COSV52339217; called by muse, mutect2, varscan2
- CHORDC1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57705153; called by muse, mutect2, varscan2
- CHORDC1 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV57705778; called by muse, mutect2, varscan2
- CIT | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV55865538, COSV99948015; called by muse, varscan2
- CLTCL1 | c.4576G>C p.E1526Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV54228322; called by muse, mutect2, varscan2
- CMSS1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV70436540; called by muse, mutect2, varscan2
- CMTM7 | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.323); catalogued as COSV58550615; called by muse, mutect2, varscan2
- COL12A1 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV59388481; called by muse, mutect2, varscan2
- CREG2 | c.612-1G>A p.X204_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV61316460; called by muse, mutect2
- CSNK1G1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV57308268; called by muse, mutect2, varscan2
- CYP11B2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV100010714; called by muse, mutect2
- CYP4F12 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs763786060, COSV61173292; called by muse, mutect2, varscan2
- CYP4F2 | c.698C>G p.S233* | Nonsense Mutation (SNP) | VAF 66/124 reads (53%) | catalogued as COSV50000049; called by muse, mutect2, varscan2
- DCST1 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV55057944; called by muse, mutect2, varscan2
- DENND1B | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs1356731439, COSV52463346; called by muse, mutect2, varscan2
- DHX16 | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV64563588, COSV64564477; called by muse, mutect2, varscan2
- DISP1 | c.3807G>C p.Q1269H | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV52657332; called by muse, mutect2, varscan2
- DNAH1 | c.7274C>G p.S2425C | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV70227948; called by muse, mutect2, varscan2
- DNAH9 | c.7366G>C p.E2456Q | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52344450; called by muse, mutect2, varscan2
- DOP1A | c.4360G>C p.E1454Q | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52708904; called by muse, mutect2, varscan2
- EP300 | c.3562G>C p.D1188H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54330518, COSV99078973; called by muse, mutect2, varscan2
- EP300 | c.3633G>T p.E1211D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.062); catalogued as rs748106711, COSV54330531; called by muse, mutect2, varscan2
- ERI3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV64831048; called by muse, mutect2, varscan2
- ETV5 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 162/391 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60501011; called by muse, mutect2, varscan2
- EXOC6 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53322475; called by muse, mutect2, varscan2
- FAM193A | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV100218625; called by muse, mutect2, varscan2
- FAM193A | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 298/386 reads (77%) | catalogued as COSV100218629; called by muse, mutect2, varscan2
- FGD2 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV51463072; called by muse, mutect2, varscan2
- FGD2 | c.822G>C p.Q274H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV51463085; called by muse, mutect2, varscan2
- FGD2 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as COSV51463094; called by muse, mutect2, varscan2
- FGGY | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV58030813; called by muse, mutect2, varscan2
- FOXM1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs779297675, COSV61205730; called by muse, mutect2, varscan2
- FOXN1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs1220212347, COSV56881338; called by muse, mutect2, varscan2
- FPGT | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63837780; called by muse, mutect2, varscan2
- FRMD4A | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1163171431, COSV52719703; called by muse, mutect2, varscan2
- FSHR | c.1947G>A p.M649I | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV58621375; called by muse, mutect2, varscan2
- GALNTL5 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442580697, COSV67179766; called by muse, mutect2, varscan2
- GBP7 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs1406441084, COSV54009175, COSV54011394; called by muse, mutect2, varscan2
- GBP7 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 47/99 reads (47%) | catalogued as COSV99642858; called by muse, mutect2, varscan2
- GDPGP1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61575720; called by muse, mutect2, varscan2
- GEMIN5 | c.2099C>T p.S700L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV53559772, COSV99593689; called by muse, mutect2, varscan2
- GGH | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52650002; called by muse, mutect2, varscan2
- GLS2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV61737155, COSV61737803; called by muse, mutect2, varscan2
- GPATCH8 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.907); catalogued as COSV59194155; called by muse, mutect2, varscan2
- GRM7 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV63138569; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2408G>T p.R803L (on ENST00000265755 / NM_016328.3; = p.R788L on NM_005685.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs587668148, COSV56085867; called by muse, mutect2, varscan2
- GTPBP2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV61076008; called by muse, mutect2, varscan2
- HACE1 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV53501481; called by muse, mutect2, varscan2
- HASPIN | c.11C>G p.S4W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs778982419, COSV53992620; called by muse, mutect2, varscan2
- HECTD1 | c.4484C>T p.S1495F | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67945809; called by muse, mutect2, varscan2
- HELQ | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1391196376, COSV55024779; called by muse, mutect2, varscan2
- HOXA3 | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV57825913; called by muse, mutect2
- HSP90AB1 | c.188C>A p.S63* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100806952; called by muse, mutect2, varscan2
- ICE1 | c.4189C>T p.Q1397* | Nonsense Mutation (SNP) | VAF 36/47 reads (77%) | catalogued as COSV99663854; called by muse, varscan2
- INPP4B | c.1159A>G p.R387G | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV53719624; called by muse, mutect2, varscan2
- IRS4 | c.2697T>A p.Y899* | Nonsense Mutation (SNP) | VAF 111/126 reads (88%) | catalogued as COSV100929441; called by muse, mutect2, varscan2
- ITIH1 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV56253980; called by muse, mutect2, varscan2
- ITPR1 | c.3868G>A p.E1290K (on ENST00000354582; = p.E1275K on NM_002222.7) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56976920; called by muse, mutect2, varscan2
- KCNA6 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54974736; called by muse, mutect2, varscan2
- KCNIP1 | c.634G>C p.E212Q (on ENST00000411494 / NM_001034837.3; = p.E201Q on NM_014592.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61083104; called by muse, mutect2, varscan2
- KCTD15 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV52289705; called by muse, mutect2, varscan2
- KNL1 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV61153371; called by muse, mutect2, varscan2
- LIF | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.47); catalogued as COSV50776598; called by muse, mutect2, varscan2
- LRP1B | c.6475C>T p.L2159F | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV67204699; called by muse, mutect2, varscan2
- LRRC37A3 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV100140872; called by muse, mutect2, varscan2
- LSG1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0.065); catalogued as COSV54569427; called by muse, mutect2, varscan2
- LY75 | c.3340C>G p.L1114V | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.367); catalogued as COSV55104168; called by muse, mutect2, varscan2
- LYPD4 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV58027712; called by muse, mutect2, varscan2
- M1AP | c.1535C>A p.S512Y | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV51206922, COSV99283890; called by muse, mutect2, varscan2
- MAN2B1 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54418087; called by muse, mutect2, varscan2
- MAST1 | c.2165C>G p.S722W | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52244672; called by muse, mutect2, varscan2
- MED1 | c.4673C>G p.S1558* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | catalogued as COSV100327435, COSV100328071; called by muse, mutect2, varscan2
- METTL21C | c.690C>G p.D230E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV57432488; called by muse, mutect2, varscan2
- MFSD1 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as COSV51840102; called by muse, mutect2, varscan2
- MFSD14B | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV64700647; called by muse, mutect2, varscan2
- MIA3 | c.3210G>T p.K1070N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1558179158, COSV60511817; called by muse, mutect2, varscan2
- MON2 | c.5063C>T p.S1688L | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV54805652; called by muse, mutect2, varscan2
- MORC1 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV51717798; called by muse, mutect2, varscan2
- MOSPD2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 62/69 reads (90%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV66859888; called by muse, mutect2, varscan2
- MRTFA | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62932586; called by muse, mutect2, varscan2
- MTHFD2L | c.206G>A p.R69Q (on ENST00000395759 / NM_001144978.2; = p.R11Q on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs765921680, COSV57466788; called by muse, mutect2, varscan2
- MTO1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV64773586; called by muse, mutect2, varscan2
- MYH2 | c.5128C>T p.Q1710* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs1180452225, COSV99819339; called by muse, mutect2, varscan2
- MYO6 | c.1115T>C p.L372S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1014537002, COSV64118533; called by muse, mutect2, varscan2
- MYO9A | c.7331C>T p.S2444F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.817); catalogued as COSV61849548; called by muse, mutect2, varscan2
- MYO9A | c.4448C>T p.S1483F | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV61849553; called by muse, mutect2, varscan2
- MZB1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs372851416, COSV56172066; called by muse, mutect2, varscan2
- NAA16 | c.1606C>A p.R536S | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101038253, COSV65064853; called by muse, mutect2, varscan2
- NARS2 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs901853447, COSV99806972; called by muse, mutect2
- NBR1 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs377650248; called by muse, mutect2, varscan2
- NLRP1 | c.684G>C p.E228D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as rs772454679, COSV52561014, COSV52563592; called by muse, mutect2, varscan2
- NR2C2 | c.653G>A p.R218K (on ENST00000393102; = p.R237K on NM_003298.5) | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.101); catalogued as COSV60145718; called by muse, mutect2, varscan2
- OR4P4 | c.826A>T p.I276F | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs767853483, COSV58921481; called by muse, mutect2, varscan2
- OXCT2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.045); catalogued as COSV59593643; called by muse, mutect2, varscan2
- PAK6 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs141761526; called by muse, mutect2, varscan2
- PARD6B | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.3); catalogued as COSV65404297; called by muse, mutect2, varscan2
- PCDH9 | c.3391C>G p.Q1131E (on ENST00000377865 / NM_203487.3; = p.Q1097E on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV60541671; called by muse, mutect2, varscan2
- PCDHGA10 | c.1448C>A p.P483Q | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV53927794; called by muse, mutect2, varscan2
- PCDHGA4 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.914); catalogued as COSV53927774; called by muse, mutect2, varscan2
- PIGS | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.266); catalogued as COSV52024116; called by muse, mutect2, varscan2
- PLA2G7 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV51259577; called by muse, mutect2, varscan2
- PLCB1 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs1466818299, COSV62046004; called by muse, mutect2, varscan2
- PLEKHO1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV50310026; called by muse, mutect2, varscan2
- PNLIPRP2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554868907, COSV53943198; called by muse, mutect2, varscan2
- PNPT1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.065); catalogued as COSV53176757; called by muse, mutect2, varscan2
- POT1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1378378085, COSV62929346; called by muse, mutect2, varscan2
- PPFIA1 | c.1917C>G p.I639M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99556903; called by muse, mutect2
- PRAG1 | c.2809C>T p.Q937* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100421904; called by muse, varscan2
- PRKD1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV59564409; called by muse, mutect2, varscan2
- PRMT5 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV53545510; called by muse, mutect2, varscan2
- PRRC2C | c.5896C>G p.Q1966E (on ENST00000367742; = p.Q1964E on NM_015172.4) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.332); catalogued as COSV58903746; called by muse, mutect2, varscan2
- PSD3 | c.3115G>A p.E1039K (on ENST00000440756; = p.E1038K on NM_015310.4) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV54069660; called by muse, mutect2, varscan2
- PSMD4 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1430482157, COSV64393247; called by muse, mutect2, varscan2
- PSTK | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV64398350; called by muse, mutect2, varscan2
- PTCHD1 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0.442); catalogued as COSV65059704; called by muse, mutect2, varscan2
- PTGS2 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 41/87 reads (47%) | catalogued as COSV66568121; called by muse, mutect2, varscan2
- QSER1 | c.1807G>C p.D603H (on ENST00000399302; = p.D732H on NM_001076786.3) | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV67900106; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as rs762764163, COSV54759257; called by muse, mutect2, varscan2
- RACGAP1 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs755241888, COSV56699005; called by muse, mutect2, varscan2
- RAPGEF6 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 40/77 reads (52%) | catalogued as COSV99725433; called by muse, mutect2, varscan2
- RCOR2 | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 103/252 reads (41%) | catalogued as COSV100035964, COSV100036051; called by muse, mutect2, varscan2
- REG1A | c.410G>A p.C137Y | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52069344, COSV52069971; called by muse, mutect2, varscan2
- REV3L | c.3337C>T p.L1113F | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1342935683, COSV62617682; called by muse, mutect2, varscan2
- RGS12 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100374622, COSV60903678; called by muse, mutect2
- RGS12 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60903732; called by muse, mutect2
- RHOA | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as COSV69041753, COSV69042135; called by muse, mutect2, varscan2
- RIPK4 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100205195, COSV60186614; called by muse, varscan2
- RLN3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs891808815, COSV54600079; called by muse, mutect2, varscan2
- RPP30 | c.495G>C p.M165I | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53295961; called by muse, mutect2, varscan2
- RRBP1 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55698535; called by muse, mutect2
- SALL1 | c.3384G>C p.R1128S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51755874; called by muse, mutect2, varscan2
- SALL2 | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58102760; called by muse, mutect2, varscan2
- SALL2 | c.2102C>T p.T701I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58102768; called by muse, mutect2, varscan2
- SALL2 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as COSV58102798; called by muse, varscan2
- SALL2 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV100444142; called by muse, varscan2
- SAMD4A | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.505); catalogued as COSV51879151; called by muse, mutect2, varscan2
- SCNN1B | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV56303229; called by muse, mutect2, varscan2
- SCUBE2 | c.544C>A p.H182N | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1246542141, COSV58541909; called by muse, mutect2, varscan2
- SEC31A | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760483691, COSV52343862; called by muse, mutect2, varscan2
- SEMA4C | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs1487148648, COSV59689501; called by muse, mutect2, varscan2
- SEZ6L | c.1486G>C p.E496Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50661005; called by muse, mutect2, varscan2
- SIN3A | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64582465; called by muse, mutect2, varscan2
- SLC37A1 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV61402042; called by muse, mutect2, varscan2
- SLC43A2 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1416971754, COSV56768614; called by muse, mutect2, varscan2
- SLCO2A1 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60484857; called by muse, mutect2, varscan2
- SLCO4A1 | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as COSV53890218, COSV53892017; called by muse, mutect2, varscan2
- SMCR8 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58176560; called by muse, mutect2, varscan2
- SMCR8 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 45/101 reads (45%) | catalogued as COSV100328934; called by muse, mutect2, varscan2
- SOGA1 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs370189773; called by muse, mutect2, varscan2
- SPECC1L | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753492834, COSV58657680; called by muse, mutect2, varscan2
- SSH3 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57384213; called by muse, mutect2, varscan2
- STRAP | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV50308393; called by muse, mutect2, varscan2
- STX2 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs757255713, COSV55432810; called by muse, mutect2, varscan2
- SULF1 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52678287, COSV52678716, COSV99483703; called by muse, mutect2, varscan2
- TAS1R3 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs766814250, COSV59562920, COSV59563582; called by muse, mutect2, varscan2
- TBC1D4 | c.2702G>A p.R901K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66488609; called by muse, mutect2, varscan2
- TDRD3 | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV52155422; called by muse, mutect2, varscan2
- TENM2 | c.6147G>C p.L2049F (on ENST00000518659 / NM_001122679.2; = p.L1810F on NM_001080428.3) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV69127482; called by muse, mutect2, varscan2
- TERF1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1444837457, COSV52580397; called by muse, varscan2
- TET2 | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV54405827; called by muse, mutect2, varscan2
- TEX30 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV65696635; called by muse, mutect2, varscan2
- TFG | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1299057778, COSV52533201, COSV99427505; called by muse, mutect2, varscan2
- THG1L | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99180224; called by muse, mutect2, varscan2
- TIGD4 | c.281G>A p.W94* | Nonsense Mutation (SNP) | VAF 44/135 reads (33%) | catalogued as COSV100427903; called by muse, mutect2, varscan2
- TIMELESS | c.3364G>A p.D1122N | Missense Mutation (SNP) | VAF 69/293 reads (24%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV57510471, COSV99973983; called by muse, mutect2, varscan2
- TLR5 | c.1507C>T p.H503Y | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV60558612; called by muse, mutect2, varscan2
- TMEM187 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs141790051, COSV64141441; called by muse, mutect2, varscan2
- TMEM200A | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1416618515, COSV51648874; called by muse, mutect2, varscan2
- TRPV3 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776459642, COSV56790382, COSV56791850; called by muse, mutect2, varscan2
- TSC1 | c.469_470del p.I157Ffs*60 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as COSV53765756; called by mutect2, pindel, varscan2
- TUT7 | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs758591070, COSV52895091, COSV99463143; called by muse, mutect2, varscan2
- TUT7 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 58/70 reads (83%) | catalogued as COSV104373453, COSV52894574; called by muse, mutect2, varscan2
- UCMA | c.206G>C p.R69T | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as COSV66321475; called by muse, mutect2, varscan2
- UPF2 | c.3552G>T p.K1184N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62659862; called by muse, varscan2
- USP15 | c.800C>T p.S267L (on ENST00000280377 / NM_001351159.2; = p.S238L on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54790603; called by muse, mutect2, varscan2
- USP47 | c.1879G>T p.E627* (on ENST00000399455 / NM_001372095.1; = p.E539* on NM_017944.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 49/127 reads (39%) | catalogued as COSV100359204, COSV60463746; called by muse, mutect2, varscan2
- VPS29 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV62194643; called by muse, mutect2, varscan2
- WDR19 | c.2920C>G p.L974V | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56463832; called by muse, mutect2, varscan2
- WDR3 | c.2787G>C p.K929N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.395); catalogued as COSV60456486; called by muse, mutect2, varscan2
- XIRP2 | c.5963C>T p.P1988L (on ENST00000628543; = p.P2163L on NM_152381.6) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1328835832, COSV54693060; called by muse, mutect2, varscan2
- XKR7 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.769); catalogued as rs781133344, COSV73813021, COSV73813122; called by muse, mutect2, varscan2
- ZFHX3 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs544260229, COSV51714679; called by muse, mutect2, varscan2
- ZFHX3 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV51714692; called by muse, mutect2, varscan2
- ZFR2 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs768433061, COSV53597693; called by muse, varscan2
- ZNF407 | c.4232C>T p.S1411F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV55248915; called by muse, mutect2, varscan2
- ZNF580 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1472002292, COSV54401303; called by muse, mutect2, varscan2
- ZNF605 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV59159528; called by muse, mutect2, varscan2
- ZNF91 | c.855G>C p.K285N | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV56083206; called by muse, mutect2, varscan2
- ZSCAN10 | c.742C>T p.P248S (on ENST00000252463; = p.P303S on NM_032805.3) | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV52967489; called by muse, mutect2, varscan2
- ZSCAN29 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53018477; called by muse, mutect2, varscan2
- ZSCAN9 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52849517, COSV99356443; called by muse, mutect2, varscan2
- ABCC9 | c.3600del p.E1200Dfs*2 | Frame Shift Del (DEL) | VAF 42/115 reads (37%) | called by mutect2, pindel, varscan2
- ARHGAP29 | c.690dup p.N231* | Frame Shift Ins (INS) | VAF 42/108 reads (39%) | called by mutect2, pindel, varscan2
- CDK11A | c.469G>C p.E157Q (on ENST00000378633 / NM_001313896.2; = p.E167Q on NM_024011.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.841); called by mutect2, varscan2
- EPHA2 | c.1379dup p.P461Afs*135 | Frame Shift Ins (INS) | VAF 43/72 reads (60%) | called by mutect2, pindel, varscan2
- FAM168B | c.195del p.T66Pfs*97 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- SLC9A5 | c.2097del p.V700Wfs*102 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- AHNAK | c.13140C>T p.I4380= | Silent (SNP) | VAF 80/216 reads (37%) | catalogued as COSV57210122; called by muse, mutect2, varscan2
- AHNAK | c.12588C>T p.F4196= | Silent (SNP) | VAF 207/447 reads (46%) | catalogued as rs753178284, COSV57210138; called by muse, mutect2, varscan2
- AKR1B15 | c.390G>C p.L130= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as COSV71151535, COSV71152658; called by muse, mutect2, varscan2
- AP3B2 | c.1218C>T p.N406= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV55608472; called by muse, mutect2, varscan2
- ATXN3 | c.747C>G p.L249= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV61494601; called by muse, mutect2, varscan2
- B3GAT3 | c.18G>A p.K6= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs754960750, COSV55488411; called by muse, mutect2, varscan2
- BRAF | c.2103C>T p.N701= (on ENST00000288602 / NM_001374244.1; = p.N661= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1316043287, COSV56136502; called by muse, mutect2, varscan2
- CCDC130 | c.693G>A p.L231= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs776045791, COSV50004101; called by muse, mutect2, varscan2
- CCDC59 | c.277C>T p.L93= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs541093825, COSV50258473; called by muse, mutect2, varscan2
- CCNF | c.999G>T p.L333= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV53539259; called by muse, mutect2, varscan2
- CDH11 | c.201C>T p.T67= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs377458530; called by muse, varscan2
- CFAP298-TCP10L | c.543C>G p.L181= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV51591617; called by muse, mutect2, varscan2
- CHRM2 | c.1365C>T p.L455= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as rs1159399936, COSV100280400, COSV57769505; called by muse, mutect2, varscan2
- COL22A1 | c.4356A>G p.P1452= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV57331819; called by muse, mutect2, varscan2
- COX11 | c.357C>G p.L119= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV54802749; called by muse, mutect2, varscan2
- CRAMP1 | c.3366G>A p.L1122= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1197072329, COSV51961102, COSV99246524; called by muse, mutect2, varscan2
- CTC1 | c.480C>T p.F160= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs758526155, COSV59852873, COSV59854186; called by muse, varscan2
- CYP4F12 | c.171G>A p.R57= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV61172385; called by muse, mutect2, varscan2
- DBNL | c.1185G>A p.E395= (on ENST00000448521 / NM_001014436.3; = p.E396= on NM_014063.7) | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV51977593; called by muse, mutect2, varscan2
- DCST1 | c.603G>A p.V201= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs748871200, COSV55057931; called by muse, mutect2, varscan2
- DCST1 | c.1110G>A p.L370= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs1224369008, COSV55058194; called by muse, mutect2, varscan2
- DEFA6 | c.288A>G p.R96= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV52405892; called by muse, mutect2, varscan2
- DHX34 | c.969C>T p.F323= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV60895037; called by muse, mutect2, varscan2
- DOT1L | c.1575C>T p.L525= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV67107853; called by muse, mutect2, varscan2
- DPAGT1 | c.984C>T p.F328= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV53828120; called by muse, mutect2, varscan2
- EPHA1 | c.1368G>A p.V456= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV51970315; called by muse, mutect2, varscan2
- FERMT2 | c.189C>G p.L63= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV58406258; called by muse, mutect2, varscan2
- FSTL5 | c.1125G>A p.L375= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV60189133; called by muse, mutect2, varscan2
- HCN1 | c.1371G>T p.L457= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs561869170, COSV57491077, COSV57497442, COSV57503513; called by muse, mutect2, varscan2
- IGF1R | c.2016G>A p.K672= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV51278290; called by muse, mutect2, varscan2
- INPP5D | c.3075G>A p.L1025= (on ENST00000445964 / NM_001017915.3; = p.L1024= on NM_005541.5) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs752632052, COSV64036494; called by muse, mutect2, varscan2
- ITGB5 | c.774C>G p.V258= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV56148141; called by muse, mutect2, varscan2
- KCNA3 | c.669C>G p.L223= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV63901297; called by muse, mutect2, varscan2
- KCNB1 | c.786C>G p.L262= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV65567236; called by muse, mutect2, varscan2
- KPNB1 | c.2076G>A p.V692= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV51596231; called by muse, mutect2, varscan2
- MRGPRX4 | c.732G>T p.L244= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV58590292; called by muse, varscan2
- MYO9A | c.1746C>T p.I582= | Silent (SNP) | VAF 57/120 reads (48%) | catalogued as COSV61849557; called by muse, mutect2, varscan2
- NTHL1 | c.42G>C p.A14= (on ENST00000219066; = p.A6= on NM_002528.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99526131; called by muse, mutect2
- NTRK1 | c.1782C>T p.H594= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs373158861; called by muse, varscan2
- ORAI2 | c.633C>T p.F211= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs144660402; called by muse, mutect2, varscan2
- P2RY8 | c.219C>T p.A73= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV67177084; called by muse, mutect2, varscan2
- PAX8 | c.294G>A p.Q98= | Silent (SNP) | VAF 145/329 reads (44%) | catalogued as COSV54507680; called by muse, mutect2, varscan2
- PCDHGA2 | c.2334G>A p.T778= | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as rs773019891, COSV53906585; called by muse, mutect2, varscan2
- PIK3CA | c.2889G>A p.V963= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV55908115; called by muse, mutect2, varscan2
- PIM3 | c.612C>T p.F204= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs956358198, COSV62259610; called by muse, mutect2, varscan2
- PKNOX2 | c.843G>A p.L281= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV100021804, COSV53543915; called by muse, mutect2, varscan2
- PPM1A | c.858G>A p.V286= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV57786354, COSV57788035; called by muse, mutect2, varscan2
- PPP2R2B | c.1134G>A p.S378= (on ENST00000394409; = p.S444= on NM_181674.2) | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as rs762618595, COSV60761871; called by muse, mutect2, varscan2
- PRAG1 | c.2874C>G p.L958= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as rs770486196, COSV58159763; called by muse, varscan2
- PRC1 | c.993C>G p.L331= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as COSV62694960; called by muse, mutect2, varscan2
- PRLHR | c.1029C>T p.R343= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs752693520, COSV53303521; called by muse, mutect2, varscan2
- PRR5L | c.133C>T p.L45= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs1372897528, COSV61120889; called by muse, mutect2, varscan2
- PUF60 | c.999C>T p.I333= (on ENST00000526683 / NM_001362896.2; = p.I316= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1291042916, COSV57585119; called by muse, varscan2
- PUF60 | c.867C>G p.L289= (on ENST00000526683 / NM_001362896.2; = p.L272= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV57585122; called by muse, varscan2
- PYGB | c.1473G>A p.R491= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1016325964, COSV53817536; called by muse, mutect2, varscan2
- RAD51D | c.39C>G p.T13= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs146448657; ClinVar: likely benign; called by muse, mutect2, varscan2
- REC8 | c.1173G>A p.R391= | Silent (SNP) | VAF 61/188 reads (32%) | catalogued as COSV61015916; called by muse, mutect2, varscan2
- RNF216 | c.2037G>A p.G679= (on ENST00000425013 / NM_207116.3; = p.G736= on NM_207111.4) | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV66290043; called by muse, mutect2, varscan2
- RPS6KA2 | c.1401G>A p.P467= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs375364710; called by muse, mutect2, varscan2
- RTKN | c.618G>C p.L206= (on ENST00000272430 / NM_001015055.2; = p.L193= on NM_033046.2) | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs556202330, COSV51962384; called by muse, mutect2, varscan2
- SALL2 | c.129C>T p.F43= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs867929116, COSV58102805; called by muse, mutect2, varscan2
- SCN11A | c.681C>T p.F227= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV56568486; called by muse, mutect2, varscan2
- SCTR | c.1041G>C p.L347= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV50027432; called by muse, mutect2, varscan2
- SEMA3E | c.435C>T p.I145= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV57085636; called by muse, mutect2, varscan2
- SH3TC2 | c.3396G>C p.L1132= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV60462401; called by muse, mutect2, varscan2
- SLC15A3 | c.159C>T p.T53= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1191622003, COSV99928369; called by muse, mutect2, varscan2
- SLC16A5 | c.1050C>T p.F350= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV61675745; called by muse, mutect2, varscan2
- SLC32A1 | c.780C>G p.L260= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV54146319; called by muse, mutect2, varscan2
- SLC39A12 | c.450C>G p.L150= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV66197148; called by muse, mutect2, varscan2
- SLC5A5 | c.315C>T p.F105= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV55832341; called by muse, mutect2, varscan2
- SMARCD2 | c.790C>T p.L264= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV56738655; called by muse, mutect2, varscan2
- SNTG1 | c.438C>G p.L146= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV52436515; called by muse, mutect2, varscan2
- SRL | c.1023C>T p.R341= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV68423167; called by muse, mutect2, varscan2
- STAT5B | c.1953C>T p.F651= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV53181783; called by muse, mutect2, varscan2
- TAS1R3 | c.912G>A p.L304= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs1283949546, COSV100229283; called by muse, mutect2, varscan2
- TMEM161B | c.1137G>A p.V379= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV56930442; called by muse, mutect2, varscan2
- TNFRSF10D | c.660C>T p.V220= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV57035294; called by muse, mutect2, varscan2
- TRIM16 | c.1236C>T p.F412= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs746252246, COSV100371730; called by muse, mutect2, varscan2
- USP14 | c.1188G>A p.Q396= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV55274759; called by muse, mutect2, varscan2
- USP36 | c.3357C>T p.L1119= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV61751127; called by muse, mutect2, varscan2
- VPS33B | c.1356C>T p.L452= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV60979759; called by muse, mutect2, varscan2
- YTHDF2 | c.201C>T p.S67= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as rs201869265; called by muse, mutect2, varscan2
- ZNF184 | c.1395G>A p.L465= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV53003890; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849447 G>A | 5'Flank (SNP) | VAF 22/26 reads (85%) | called by muse, mutect2, varscan2
- CRTC2 | c.-1G>C | 5'UTR (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100135350; called by muse, varscan2
- DCHS2 | n.1755G>A | RNA (SNP) | VAF 26/87 reads (30%) | catalogued as COSV59723158; called by muse, mutect2, varscan2
- EXT2 | c.1173+14115A>G | Intron (SNP) | VAF 34/100 reads (34%) | catalogued as rs747999174, COSV59148609; called by muse, mutect2, varscan2
- SLC22A20P | n.2450G>A | RNA (SNP) | VAF 9/22 reads (41%) | catalogued as rs1193879046; called by muse, mutect2, varscan2
- SLC30A2 | c.271+692G>T | Intron (SNP) | VAF 38/47 reads (81%) | catalogued as CM158603, COSV65332546; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 12/24 reads (50%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
